Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3O6, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3O6-01A (Primary Tumor).

[page 1 of 2]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name:	[Redacted]	Service:	[Redacted]	Accession #:	[Redacted]
MRN:	[Redacted]	Visit #:	[Redacted]	Collector:	[Redacted]
DOB:	[Redacted]	Location:	[Redacted]	Receiver:	[Redacted]
Gender:	[Redacted]	Facility:	[Redacted]	Reporter:	[Redacted]
HCM:	[Redacted]				
Ordering MD:	[Redacted]				
Copy To:	[Redacted]				

Specimen(s) Received

1. Thyroid: RIGHT HEMI THYROID STITCH UPPER POLE FOR TUMOUR BANK

Diagnosis

Papillary carcinoma, follicular variant 4.0 cm, right: Thyroid
No pathological diagnosis: Parathyroid, right
-Right hemithyroidectomy specimen.

Comment

This case has been seen in consultation with Dr. [Redacted] and she agrees with the interpretation and diagnosis.

Synoptic Data

Clinical History:	Other: BRCA1 mutation
Procedure:	Right hemithyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	4.2 cm
	2.6 cm
	1.8 cm
	Isthmus +/- pyramidal lobe:
	1.0 cm
	0.5 cm
	0.4 cm
Specimen Weight:	11.3 g
Tumor Focality:	Unifocal
----- DOMINANT TUMOR -----	
Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 4.0cm
	Additional dimension: 2.4 cm
	Additional dimension: 1.2 cm
Histologic Type:	Papillary carcinoma, follicular variant
	Follicular architecture
	Classical cytomorphology
	Oncocytic or oxyphilic cytomorphology
Histologic Grade:	Not applicable

ICD-0-3
carcinoma, papillary, follicular variant
8340/3
Site: thyroid, NOS C73.9
hw 2/5/12

[page 2 of 2]
Surgical Pathology Consultation Report

Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assigned Number of regional lymph nodes examined: 0 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Parathyroid gland(s), within normal limits
Ancillary Studies:	Type: IHC Results: The tumor shows diffuse weak positivity for CK19. HBME-1 and Galectin-3 are negative.

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Gross Description

The specimen labeled with the patient's name and as "right hemithyroid stitch upper pole", consists of a right hemithyroidectomy specimen that is oriented with a suture on the upper pole and weighs 11.3 g. The lobe measures 4.2 cm SI x 2.6 cm ML x 1.8 cm AP and the isthmus measures 1.0 SI x 0.4 cm ML x 0.5 cm AP. The external surfaces have fibrous adhesions and painted with blue ink. No parathyroid glands and/or no lymph nodes are identified grossly. The right lobe contains a single delineated nodule that measure 4.0 cm SI x 2.4 cm ML x 1.2 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of nodule are stored frozen. The remainder of the specimen is submitted as follows:

1A-G lobe, superior to inferior
1H isthmus

Source: NCI Genomic Data Commons file db90e97b-485b-404d-89e8-3c8ff721dc4d (TCGA-EM-A3O6.849896B6-D6BA-44EA-8818-FA80E6B7E797.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).